Somatic mutation profile of tumor specimen TCGA-OR-A5LR-01A (aliquot TCGA-OR-A5LR-01A-11D-A29I-10) from TCGA case TCGA-OR-A5LR, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 30.8 years (11,261 days).
Specimen TCGA-OR-A5LR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f6f4070-592b-487b-a942-a0f523179940.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5LR-10A (Blood Derived Normal), aliquot TCGA-OR-A5LR-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35b3c965-92b9-4ccc-9771-00bc5eb745d4

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Translation Start Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEMIP2 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.634); catalogued as rs768736110, COSV65487561; called by muse, mutect2, varscan2
- H3C4 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 13/273 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); catalogued as COSV61912423; called by muse, mutect2
- SP2 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1432473076; called by muse, mutect2
- GNAL | c.148G>A p.A50T (on ENST00000269162 / NM_001142339.3; = p.A127T on NM_182978.4) | Missense Mutation (SNP) | VAF 80/104 reads (77%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HLTF | c.2066T>C p.I689T | Missense Mutation (SNP) | VAF 62/88 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- HSF1 | c.569T>A p.I190N | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- KLRB1 | c.280T>A p.C94S | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- MUC16 | c.24193A>G p.S8065G | Missense Mutation (SNP) | VAF 109/159 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR51D1 | c.747G>T p.K249N | Missense Mutation (SNP) | VAF 65/76 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RUNX1 | c.208T>C p.F70L (on ENST00000344691 / NM_001001890.3; = p.F97L on NM_001754.5) | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SH3BGRL2 | c.306A>G p.A102= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV63964750; called by muse, mutect2, varscan2
